Gene-level copy-number profile of tumor specimen MP2PRT-PAPFFW-TMP1-A from MP2PRT case MP2PRT-PAPFFW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,148 days).
Specimen MP2PRT-PAPFFW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4cbd8de1-9078-4e65-b4d6-50622146025f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPFFW-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/e1d487af-f557-4c75-aea6-5399237d0f70

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,124; copy number 1: 13,154; copy number 2: 43,643; copy number 3: 950; copy number 4: 37.

Homozygous deletions (total copy number 0; autosomes only): 972 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:45,493,866–45,570,049, 5 genes: CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1.
- chr1:248,810,446–248,937,043, 8 genes: SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:68,361,214–68,467,294, 4 genes: AC015969.1, PLEK, AC127383.1, FBXO48.
- chr2:88,811,186–91,580,863, 94 genes (within-gene range 0–2) (broad region; genes not listed).
- chr2:196,133,583–196,176,503, 2 genes: STK17B, AC114760.2.
- chr2:201,182,898–201,287,711, 5 genes: CASP10, MTND5P25, MTND4P23, MTND4LP13, CASP8.
- chr3:36,826,819–36,993,131, 6 genes: TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1.
- chr5:181,178,821–181,342,213, 20 genes: LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:2,851,230–2,881,407, 2 genes: SERPINB9P1, MIR4645.
- chr6:25,962,802–26,606,661, 60 genes: TRIM38, U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P, BTN3A2, BTN2A2, BTN3A1, BTN2A3P, BTN3A3, BTN2A1, BTN1A1, RNU6-502P, HCG11, HMGN4, ABT1, AL513548.3.
- chr6:32,578,769–33,457,544, 69 genes (broad region; genes not listed).
- chr6:159,669,069–159,798,436, 10 genes: SOD2, HNRNPH1P1, RNU4ATAC18P, WTAP, SOD2-OT1, ACAT2, TCP1, SNORA20, SNORA29, MRPL18.
- chr7:38,239,580–38,378,804, 24 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1.
- chr7:100,015,572–100,707,486, 57 genes: ZKSCAN1, ZSCAN21, ZNF3, COPS6, MCM7, MIR25, MIR93, MIR106B, AP4M1, TAF6, AC073842.2, CNPY4, MBLAC1, AC073842.1, RPL7P60, LAMTOR4, MAP11, MIR4658, GAL3ST4, GPC2, STAG3, CASTOR3, PVRIG, SPDYE3, PMS2P1, Y_RNA, STAG3L5P, STAG3L5P-PVRIG2P-PILRB, PILRB, PVRIG2P, MIR6840, PILRA, AC005071.1, ZCWPW1, MEPCE, AC092849.1, PPP1R35, PPP1R35-AS1, C7orf61, TSC22D4, NYAP1, AC069281.1, RN7SL416P, AGFG2, IRS3P, SAP25, AC069281.2, LRCH4, FBXO24, PCOLCE-AS1, PCOLCE, MOSPD3, TFR2, ACTL6B, GNB2, GIGYF1, POP7.
- chr10:72,216,000–72,355,149, 5 genes (within-gene range 0–1): ANAPC16, Y_RNA, DDIT4, DDIT4-AS1, DNAJB12.
- chr10:96,743,167–96,750,899, 2 genes: RNU6-1274P, RPL13AP5.
- chr10:109,996,368–110,135,565, 1 gene (within-gene range 0–2): ADD3.
- chr11:62,545,999–62,888,875, 51 genes (within-gene range 0–2): AP001363.2, EEF1G, AP002990.1, MIR6747, TUT1, MTA2, EML3, AP001458.1, ROM1, B3GAT3, GANAB, INTS5, AP001458.2, C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1, LRRN4CL, BSCL2, HNRNPUL2-BSCL2, GNG3, HNRNPUL2, TTC9C, ZBTB3, POLR2G, AP001160.2, TAF6L, TMEM223, AP001160.3, TMEM179B, MIR6748, NXF1, MIR6514, STX5, AP001160.4, RNU6-118P, AP001160.1, TEX54, WDR74, RNU2-2P, SNHG1, SNORD22, SNORD30, SNORD22, SNORD28, SNORD27, SNORD26, SNORD25, SLC3A2.
- chr12:49,086,656–49,189,080, 7 genes (within-gene range 0–1): DHH, AC011603.1, LMBR1L, TUBA1B, AC011603.2, Y_RNA, TUBA1A.
- chr12:49,196,784–49,197,062, 1 gene (within-gene range 0–1): Metazoa_SRP.
- chr12:110,372,900–110,533,556, 11 genes (within-gene range 0–1): ANAPC7, AC144548.1, HMGA1P3, ARPC3, GPN3, RPL31P49, FAM216A, VPS29, AC002350.1, AC002350.2, RAD9B.
- chr13:40,931,924–41,061,440, 2 genes (within-gene range 0–2): ELF1, RGS17P1.
- chr14:22,556,311–22,598,946, 4 genes (within-gene range 0–2): LINC02332, AC243965.1, DAD1, AC243965.2.
- chr14:24,070,837–24,340,022, 43 genes: CPNE6, NRL, PCK2, DCAF11, AL136295.3, FITM1, PSME1, EMC9, AL136295.2, PSME2, MIR7703, RNF31, AL136295.5, RNA5SP383, IRF9, REC8, IPO4, AL136295.4, AL136295.22, TM9SF1, AL136295.1, AL136295.6, AL136295.7, TSSK4, CHMP4A, AL096870.2, MDP1, NEDD8-MDP1, NEDD8, GMPR2, TINF2, TGM1, RABGGTA, AL096870.12, AL096870.10, DHRS1, NOP9, CIDEB, LTB4R2, LTB4R, ADCY4, AL096870.1, RIPK3.
- chr14:91,457,611–91,510,554, 1 gene: PPP4R3A.
- chr14:105,672,308–106,879,812, 186 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:92,795,647–92,949,230, 5 genes (within-gene range 0–2): ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1.
- chr15:92,904,399–92,904,475, 1 gene (within-gene range 0–2): MIR3175.
- chr17:28,275,986–30,117,497, 116 genes (within-gene range 0–2) (broad region; genes not listed).
- chr19:1,782,075–3,869,038, 116 genes (broad region; genes not listed).
- chr19:36,489,649–36,831,596, 15 genes (within-gene range 0–2): AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1.
- chr20:63,942,631–63,956,985, 2 genes (within-gene range 0–1): MIR647, UCKL1-AS1.
- chr21:33,229,901–33,479,348, 7 genes (within-gene range 0–2): IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2.
- chr22:22,032,745–22,230,469, 30 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,450. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
